Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RU, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RU-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma, grade II
9450/3
Site: ^{CSCF} Brain, supratentorial NOS
^{Path} C71.0
Brain, insula C71.0
QW18/4/13

Nature of material: Brain

Received on:

Macroscopy:

Received two light brown segments of the brain, with brownish and friable areas, weighing 11g and measuring 4.5 x 3.5 x 2.0 cm.

Microscopy:

Histological sections stained with hematoxylin and eosin sections show neocortex partially infiltrated by neuroepithelial neoplasm of white matter, represented by rounded nuclei cell, with granular chromatin and inconspicuous nucleoli. The cytoplasm is clear and sparse, with frequent perinuclear halos. The tumor infiltrates, in some areas, the adjacent cortex, which are observed foci of neuronal satellitosis and angulated vessels (standard chicken-wire). Are not observed atypical mitosis, vessels with microvascular proliferation or necrosis foci. We also observe areas of reactive gliosis with rarefied neuropil in the adjacent parenchyma.

Diagnosis:

Excision product of lesion in the left insular region:

- oligodendroglioma grade II-WHO (ICD-O 9450/3).

PROFESSIONAL PARTICIPANTS OF REPORT

Pathology Discrepancy		✓
ICD-O Discrepancy		✓
Reviewer Initials	BTE	CSF Reviewed: 6/2/13

Source: NCI Genomic Data Commons file 73eff2fa-12f6-4744-8f34-7e80e49ebd65 (TCGA-TQ-A7RU.CD236AFF-61DC-438F-92F0-11A3ACC85845.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).